Somatic mutation profile of tumor specimen MBCProject_2185_T1_WES (aliquot MBCProject_2185_T1_WES_1) from CMI case MBCProject_2185, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 55.6 years (20,299 days).
Specimen MBCProject_2185_T1_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Bone; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9a13360-12ba-4b57-a62b-43fc6e178bde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2185_SALIVA (Saliva), aliquot MBCProject_2185_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5fdea8a-5c2a-4461-96b6-ac0266d1a235

The open-access MAF lists 49 somatic variants for this specimen: 29 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 13, Intron 4, 3'Flank 1, RNA 1, Splice Region 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 39/107 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BPTF | c.4309A>G p.S1437G | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as COSV58837378; called by muse, mutect2
- CFAP46 | c.6287C>T p.T2096M | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs760378898; called by muse, mutect2, varscan2
- DIDO1 | c.5870C>T p.P1957L | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1363137430, COSV56636076; called by muse, mutect2, varscan2
- HTR1E | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs754605700, COSV100541104; called by muse, mutect2
- MUC5B | c.2751C>G p.C917W | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101499969; called by muse, mutect2, varscan2
- MYO1H | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 64/241 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754059239, COSV99081631; called by muse, mutect2, varscan2
- NIBAN3 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1419703787; called by muse, mutect2
- NR0B1 | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 72/491 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as CD091637; called by muse, mutect2, varscan2
- PCARE | c.2881C>G p.H961D | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.293); catalogued as COSV59054817; called by muse, mutect2, varscan2
- SRR | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as rs539383715; called by muse, mutect2, varscan2
- TENM2 | c.5143C>T p.R1715C (on ENST00000518659 / NM_001122679.2; = p.R1476C on NM_001080428.3) | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs774824482, COSV69136317; called by muse, mutect2, varscan2
- TRIM33 | c.3123G>A p.M1041I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV61822927; called by muse, mutect2, varscan2
- ZFPM1 | c.403-2A>C p.X135_splice | Splice Site (SNP) | VAF 28/53 reads (53%) | catalogued as rs80224201; called by muse, varscan2
- ALCAM | c.824A>G p.N275S | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- ANKRD9 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- DAZAP2 | c.13+8C>T | Splice Region (SNP) | VAF 60/178 reads (34%) | called by muse, mutect2, varscan2
- DCP1B | c.1818C>G p.F606L | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- EDRF1 | c.1664C>T p.S555F (on ENST00000356792 / NM_001202438.2; = p.S521F on NM_015608.2) | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- EIF2AK3 | c.1421A>G p.Y474C | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IMPG2 | c.2162C>A p.P721H | Missense Mutation (SNP) | VAF 112/406 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- KANSL1L | c.923A>T p.D308V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL42 | c.1357A>G p.I453V | Missense Mutation (SNP) | VAF 280/692 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- LRRIQ4 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.154); called by muse, mutect2
- NALCN | c.54T>G p.F18L | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NCOA1 | c.2276A>T p.D759V | Missense Mutation (SNP) | VAF 78/211 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- NPR2 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RBM20 | c.421T>C p.S141P | Missense Mutation (SNP) | VAF 70/510 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- TBCCD1 | c.1322A>C p.Y441S | Missense Mutation (SNP) | VAF 131/466 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ANKRD34A | c.1302T>C p.P434= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs782661640; called by muse, mutect2, varscan2
- CHRNA7 | c.1266C>T p.H422= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs781205866; called by mutect2, varscan2
- CHRNB2 | c.1287C>T p.D429= | Silent (SNP) | VAF 8/243 reads (3%) | catalogued as rs1057524461; ClinVar: likely benign; called by muse, mutect2
- CLCN7 | c.2262C>T p.L754= | Silent (SNP) | VAF 43/174 reads (25%) | catalogued as COSV99246762; called by muse, mutect2, varscan2
- DNAH2 | c.9069G>T p.V3023= | Silent (SNP) | VAF 20/300 reads (7%) | called by muse, mutect2
- GRIK2 | c.468C>T p.L156= | Silent (SNP) | VAF 22/223 reads (10%) | catalogued as rs749394329; called by muse, mutect2, varscan2
- MCM2 | c.2475G>A p.R825= | Silent (SNP) | VAF 27/84 reads (32%) | called by muse, mutect2, varscan2
- NLRP3 | c.1692C>T p.G564= | Silent (SNP) | VAF 72/817 reads (9%) | called by muse, mutect2
- OBSCN | c.6513G>A p.P2171= | Silent (SNP) | VAF 24/137 reads (18%) | catalogued as rs1001167639; called by muse, mutect2, varscan2
- UNC79 | c.6333C>T p.T2111= (on ENST00000393151 / NM_001346218.2; = p.T1934= on NM_020818.5) | Silent (SNP) | VAF 22/226 reads (10%) | called by muse, mutect2
- ZER1 | c.1938C>T p.P646= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as rs757400257; called by muse, mutect2, varscan2
- ZNF14 | c.876T>C p.S292= | Silent (SNP) | VAF 24/74 reads (32%) | called by muse, mutect2, varscan2
- ZXDA | c.324C>T p.A108= | Silent (SNP) | VAF 48/210 reads (23%) | called by muse, mutect2, varscan2
- AC092656.1 | n.398A>T | RNA (SNP) | VAF 67/180 reads (37%) | called by muse, mutect2, varscan2
- ARFGAP2 | c.619+58C>A | Intron (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2, varscan2
- CD3D | c.56-297T>C | Intron (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- EEF2KMT | c.96+279G>T | Intron (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- IHO1 | chr3:49260955 A>T | 3'Flank (SNP) | VAF 40/273 reads (15%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159078 G>A | 5'Flank (SNP) | VAF 11/193 reads (6%) | catalogued as rs944233346; called by muse, mutect2
- TGM2 | c.1616-126C>T | Intron (SNP) | VAF 8/38 reads (21%) | catalogued as rs1339445359; called by muse, mutect2
